Gene-level copy-number profile of tumor specimen TCGA-10-0938-01A from TCGA case TCGA-10-0938, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 80.9 years (29,558 days).
Specimen TCGA-10-0938-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.b2a05747-aa38-4968-8fb8-1f27a40a4181.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-10-0938-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fccf228e-06b4-4f80-aafc-e0468e446978

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 69; copy number 1: 411; copy number 2: 6,796; copy number 3: 22,738; copy number 4: 18,405; copy number 5: 6,379; copy number 6: 2,075; copy number 7: 484; copy number 8: 1,959; copy number 9: 10; copy number 10: 221; copy number 13: 4; copy number 14: 9; copy number 16: 7; copy number 17: 62; copy number 18: 16; copy number 19: 115; copy number 20: 39; copy number 22: 10; copy number 23: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-10-0938-01): tumor purity 0.96, ploidy 3.84, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 69 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:14,027,419–14,144,468, 1 gene (within-gene range 0–1): AP001347.1.
- chr21:14,108,813–18,267,373, 67 genes (within-gene range 0–2) (broad region; genes not listed).
- chr21:23,477,641–23,490,724, 1 gene: AP000459.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,940 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:67,662,160–67,805,336, 10 genes, copy number 17: ALDH3B2, RPL37P2, UNC93B5, OR7E145P, OR7E11P, AP003385.5, AP003385.2, AP003385.4, ALG1L8P, FAM86C2P.
- chr11:68,050,740–68,121,444, 2 genes, copy number 20 (within-gene range 3–20): AP002807.1, CHKA.
- chr11:68,272,102–71,670,297, 89 genes, copy number 17–20 (broad region; genes not listed).
- chr11:72,216,601–72,290,688, 6 genes, copy number 16: FOLR2, INPPL1, PHOX2A, AP000593.2, AP000593.4, AP000593.1.
- chr11:72,302,139–72,302,965, 1 gene, copy number 16: AP000593.3.
- chr11:72,685,069–72,793,599, 1 gene, copy number 18 (within-gene range 2–18): ARAP1.
- chr11:72,754,729–73,309,361, 15 genes, copy number 18: STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2, FCHSD2, RNU6-672P, AP002381.1, AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3.
- chr11:73,400,487–73,598,189, 1 gene, copy number 19 (within-gene range 2–19): FAM168A.
- chr11:73,510,658–73,761,137, 7 genes, copy number 19: AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1.
- chr11:74,397,549–74,485,742, 1 gene, copy number 22 (within-gene range 2–22): AP001372.1.
- chr11:74,454,841–74,669,117, 7 genes, copy number 22 (within-gene range 2–22): KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2, POLD3.
- chr11:79,966,805–79,989,630, 2 genes, copy number 22: AP001541.1, AP001284.1.
- chr11:81,175,201–82,718,299, 5 genes, copy number 19–23 (within-gene range 2–24): AP003464.1, MTND4LP18, MTND6P25, MIR4300HG, AP002802.2.
- chr11:82,603,529–83,111,442, 18 genes, copy number 19: AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5.
- chr11:83,156,988–83,286,407, 9 genes, copy number 14 (within-gene range 3–14): PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B.
- chr11:103,109,410–103,895,271, 10 genes, copy number 9 (within-gene range 5–9): DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1.
- chr11:115,920,248–123,627,774, 214 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr12:564,296–9,760,901, 343 genes, copy number 7–19 (broad region; genes not listed).
- chr12:31,073,860–32,646,050, 54 genes, copy number 8 (within-gene range 5–8): DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2, Y_RNA, FGD4, RNU6-494P.
- chr19:10,221,433–15,898,077, 334 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr19:17,075,781–17,214,537, 1 gene, copy number 8 (within-gene range 6–8): MYO9B.
- chr19:17,152,588–24,163,425, 352 genes, copy number 7–8 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 119. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
